Gene-level copy-number profile of tumor specimen TCGA-91-6848-01A from TCGA case TCGA-91-6848, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.8 years (21,829 days).
Specimen TCGA-91-6848-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.17c02f48-b544-45ad-8f10-62292b26d04d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-6848-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b02a091c-421d-48aa-a822-94a8c986aaf2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 767; copy number 2: 8,033; copy number 3: 14,744; copy number 4: 16,495; copy number 5: 11,956; copy number 6: 1,929; copy number 7: 5,196; copy number 8: 126; copy number 9: 240; copy number 10: 43; copy number 11: 86; copy number 12: 82; copy number 13: 14; copy number 16: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-6848-01A-11D-1943-01): tumor purity 0.31, ploidy 3.44, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:22,137,931–24,163,425, 95 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 473 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:201,134,772–202,189,455, 43 genes, copy number 10 (within-gene range 4–10): TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, AC119427.1, TNNI1, AC096677.3, PHLDA3, AC096677.2, CSRP1, AC096677.1, RPS10P7, NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231, IPO9, MIR6739, SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP.
- chr4:54,229,280–54,859,241, 8 genes, copy number 9 (within-gene range 7–9): PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358.
- chr4:70,704,204–73,620,631, 30 genes, copy number 9–13 (within-gene range 5–13): RUFY3, GRSF1, U6, RNU6-891P, MOB1B, DCK, SLC4A4, AC096713.1, LDHAL6EP, GC, RNA5SP163, AC068721.1, NPFFR2, ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6.
- chr8:39,743,735–43,254,089, 82 genes, copy number 12 (broad region; genes not listed).
- chr14:33,597,057–38,256,093, 98 genes, copy number 9–16 (broad region; genes not listed).
- chr16:31,713,229–35,912,516, 212 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 128. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
